Somatic mutation profile of tumor specimen TCGA-KC-A7F5-01A (aliquot TCGA-KC-A7F5-01A-11D-A33T-08) from TCGA case TCGA-KC-A7F5, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 54.8 years (20,015 days).
Specimen TCGA-KC-A7F5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44cd5da6-cac6-441b-bbe6-10f55a64ba8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KC-A7F5-10A (Blood Derived Normal), aliquot TCGA-KC-A7F5-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2129cb2-c120-48f3-b2b7-bbacb6ec9da3

The open-access MAF lists 33 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 4, Frame Shift Del 2, 3'UTR 1, Nonsense Mutation 1, Splice Site 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.761_766del p.F254_N256delinsY | In Frame Del (DEL) | VAF 13/30 reads (43%) | hotspot (GDC flag); catalogued as COSV51644065; called by mutect2, pindel, varscan2
- SPOP | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 45/117 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs1057519964, COSV61653339, COSV61655858; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APBB1IP | c.833G>T p.R278I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV66134689; called by muse, mutect2, varscan2
- ARID2 | c.980T>C p.L327S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100535321, COSV57615528; called by muse, mutect2, varscan2
- ASH1L | c.3761G>T p.R1254L | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.748); catalogued as rs377320289, COSV64213738; called by muse, mutect2, varscan2
- ASXL3 | c.3497G>A p.R1166K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as COSV99323183; called by muse, mutect2, varscan2
- CATIP | c.1030G>C p.V344L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.269); catalogued as COSV99179483; called by muse, mutect2, varscan2
- CCDC110 | c.1525A>T p.K509* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as rs750219411, COSV100293636; called by muse, varscan2
- CEP152 | c.3108A>C p.Q1036H | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100358465; called by muse, mutect2, varscan2
- ERF | c.650_651insA p.F217Lfs*12 | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | catalogued as COSV99724463; called by mutect2, varscan2
- IRAK3 | c.163G>C p.V55L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.995); catalogued as COSV99705863; called by muse, mutect2, varscan2
- KRTAP10-5 | c.208A>T p.T70S | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV100551750; called by muse, mutect2, varscan2
- LRP1 | c.9040C>T p.R3014C | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.425); catalogued as rs1206981394, COSV54524565; called by muse, mutect2, varscan2
- MINDY1 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201811445, COSV56497908; called by muse, mutect2, varscan2
- MMP26 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs368459718, COSV56173504; called by muse, mutect2, varscan2
- NCOR1 | c.1218del p.M406Ifs*15 | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | catalogued as COSV51960790; called by mutect2, pindel, varscan2
- OR5D18 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs143615376, COSV100450494, COSV100450859; called by muse, mutect2, varscan2
- PAPPA2 | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1185341844, COSV100866517, COSV100866713, COSV100867066; called by muse, mutect2, varscan2
- POLR2E | c.608A>G p.Y203C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99297380; called by muse, mutect2, varscan2
- PRDM14 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99399835; called by muse, mutect2, varscan2
- SLCO1C1 | c.503A>G p.E168G | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99858431; called by muse, mutect2, varscan2
- SPRED2 | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.862); catalogued as rs556500338, COSV100710051; called by muse, mutect2, varscan2
- VPS13B | c.80A>G p.Q27R | Missense Mutation (SNP) | VAF 147/257 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100660790; called by muse, mutect2, varscan2
- XIRP2 | c.1465G>A p.D489N (on ENST00000628543; = p.D664N on NM_152381.6) | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs769903080, COSV54690919; called by muse, mutect2, varscan2
- ZNF366 | c.1351T>A p.C451S | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100574052; called by muse, mutect2, varscan2
- MRS2 | c.261_264+12del p.X87_splice | Splice Site (DEL) | VAF 10/59 reads (17%) | called by pindel, varscan2
- NOX3 | c.554del p.V185Afs*2 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | called by mutect2, pindel, varscan2
- TPTE | c.382T>G p.S128A (on ENST00000618007 / NM_199261.4; = p.S110A on NM_199259.4) | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.065); called by muse, varscan2
- FUT4 | c.96G>T p.S32= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs761018933, COSV100707960; called by muse, mutect2, varscan2
- KLF7 | c.411G>A p.T137= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs761636754, COSV58746237; called by muse, mutect2, varscan2
- PDE2A | c.1812C>T p.T604= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs1194276923, COSV100557583; called by muse, mutect2, varscan2
- PDGFB | c.312C>T p.F104= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as rs757018789, COSV58645713; called by muse, mutect2, varscan2
- PLCXD2 | c.*48C>A | 3'UTR (SNP) | VAF 52/129 reads (40%) | catalogued as COSV101208386; called by muse, mutect2, varscan2
